TCGA case TCGA-CJ-5675 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ceb7cd9a-9cb1-42f2-a4ab-0b4381e2b85b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (3)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 70.1 years (25,617 days); Year of diagnosis: 2004; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 72.6 years (26,517 days); Days to diagnosis: 900 days (2.5 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 72.6 years (26,517 days); Days to diagnosis: 900 days (2.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 900 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 2,430 days (6.7 years); Disease response: With Tumor.
- Days to follow up: 3,936 days (10.8 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Leukocytes: Normal.
- Platelets: Normal.
- Hemoglobin: Normal.
- Lactate Dehydrogenase: Normal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-5675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.6; Intermediate dimension: 0.8; Shortest dimension: 0.8.
  Slide TCGA-CJ-5675-01A-01-TS1: Section location: Top; Percent tumor cells: 88; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 12.
  Slide TCGA-CJ-5675-01A-01-BS1: Section location: Bottom; Percent tumor cells: 88; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 12.
- Sample TCGA-CJ-5675-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-5675-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 4; Intermediate dimension: 1.5; Shortest dimension: 1.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: No; Tobacco smoking history indicator: 1.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event surgery met: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome at TCGA followup: Stable Disease; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,936 days; disease-specific survival: no event (censored), 3,936 days; disease-free interval: event (new tumor event after initially disease-free), 900 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 900 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CJ-5675-01A-11D-1530-01): tumor purity 0.53, ploidy 2.02, whole-genome doublings 0.
